Gene-level copy-number profile of tumor specimen TCGA-63-A5MU-01A from TCGA case TCGA-63-A5MU, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.81872979-c054-4838-87a8-ef19c803a183.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a89e948b-c3a1-4492-927b-27eb7e839579

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 406; copy number 2: 8,164; copy number 3: 31,275; copy number 4: 8,855; copy number 5: 4,657; copy number 6: 4,229; copy number 7: 1,888; copy number 8: 164; copy number 10: 20; copy number 11: 9; copy number 15: 90; copy number 16: 17; copy number 17: 1; copy number 21: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MU-01A-11D-A26L-01): tumor purity 0.81, ploidy 3.41, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,227 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:178,685,886–179,069,594, 2 genes, copy number 7: AC017087.1, AC018710.1.
- chr8:36,987,977–41,896,762, 114 genes, copy number 7–15 (within-gene range 5–15) (broad region; genes not listed).
- chr11:68,683,779–73,996,151, 183 genes, copy number 8–21 (broad region; genes not listed).
- chr14:23,619,201–106,875,071, 1,883 genes, copy number 7–8 (broad region; genes not listed).
- chr15:45,361,124–45,703,183, 18 genes, copy number 15: GATM, AC025580.3, SPATA5L1, C15orf48, AC025580.1, MIR147B, AC025580.2, SLC30A4, HMGN2P46, SNORA41B, AC090527.1, DPPA5P2, AC090527.3, BLOC1S6, AC090527.2, Y_RNA, SQOR, AC068722.2.
- chr15:51,208,057–51,947,295, 27 genes, copy number 7 (within-gene range 4–7): CYP19A1, MIR4713, AC020891.3, MIR7973-2, MIR7973-1, AC020891.2, GLDN, AC020891.4, AC020891.1, AC066613.2, DMXL2, AC066613.1, SCG3, AC020892.1, AC020892.2, LYSMD2, TMOD2, AC026770.1, TMOD3, AC090971.5, Metazoa_SRP, AC090971.4, Y_RNA, AC090971.2, RNU6-90P, AC090971.1, AC090971.3.

Autosomal genes at a single copy (total copy number 1): 401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
